Somatic mutation profile of tumor specimen TCGA-B9-4117-01A (aliquot TCGA-B9-4117-01A-01D-1252-08) from TCGA case TCGA-B9-4117, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 48.2 years (17,622 days).
Specimen TCGA-B9-4117-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38e2e959-9f94-4efa-bf58-6a0b04e62058.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B9-4117-10A (Blood Derived Normal), aliquot TCGA-B9-4117-10A-01D-1252-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f1472b2-3fe6-459d-be12-6201754c86f0

The open-access MAF lists 44 somatic variants for this specimen: 32 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 10, Nonsense Mutation 2, In Frame Del 2, Intron 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ESF1 | c.2308T>A p.L770M | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs751395034; called by muse, mutect2, varscan2
- MEGF10 | c.1207G>A p.G403R | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1431165906; called by muse, mutect2, varscan2
- NUCB1 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs763934546; called by muse, mutect2, varscan2
- PDCD6 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs368897410; called by muse, mutect2
- SLC43A3 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs148055054; called by muse, mutect2, varscan2
- ST3GAL4 | c.130G>C p.E44Q (on ENST00000392669 / NM_001254758.1; = p.E40Q on NM_006278.3) | Missense Mutation (SNP) | VAF 145/389 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.105); catalogued as COSV57109797; called by muse, mutect2, varscan2
- TUT7 | c.1747C>G p.R583G | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52898839; called by muse, mutect2, varscan2
- ACAD10 | c.1591T>A p.Y531N | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- AHCY | c.1225_1245del p.L409_Q415del | In Frame Del (DEL) | VAF 28/110 reads (25%) | called by mutect2, pindel, varscan2
- ALS2 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 54/116 reads (47%) | called by muse, mutect2, varscan2
- C5orf51 | c.467A>T p.K156I | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CAV2 | c.214T>A p.C72S | Missense Mutation (SNP) | VAF 88/337 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- CEBPZ | c.1484C>T p.P495L | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLMN | c.2288A>G p.Y763C | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CREBBP | c.3365T>C p.I1122T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DPYSL2 | c.1161T>A p.N387K | Missense Mutation (SNP) | VAF 117/187 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DTX3L | c.115G>T p.G39W | Missense Mutation (SNP) | VAF 59/339 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EP400 | c.8714T>A p.I2905N | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXO22 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 82/283 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- GHDC | c.366C>A p.D122E | Missense Mutation (SNP) | VAF 224/664 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, varscan2
- HERPUD1 | c.354G>T p.E118D | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT tolerated (0.61); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MAOA | c.800A>C p.K267T | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- MYBPC1 | c.798A>T p.K266N (on ENST00000550270 / NM_206820.2; = p.K291N on NM_002465.4) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NSUN2 | c.959C>A p.T320K | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHJ1 | c.343C>A p.L115I | Missense Mutation (SNP) | VAF 168/513 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- RELB | c.421_423del p.R141del | In Frame Del (DEL) | VAF 26/60 reads (43%) | called by mutect2, pindel, varscan2
- SEC31B | c.2433G>C p.E811D | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TFCP2L1 | c.5T>A p.L2H | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- TMEM214 | c.799T>G p.F267V | Missense Mutation (SNP) | VAF 166/581 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- UBA2 | c.142G>C p.D48H | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- URGCP | c.2567del p.G856Afs*36 (on ENST00000453200 / NM_001077663.3; = p.G847Afs*36 on NM_017920.4) | Frame Shift Del (DEL) | VAF 26/120 reads (22%) | called by mutect2, pindel, varscan2
- ZNF665 | c.1264A>T p.K422* (on ENST00000600412; = p.K487* on NM_024733.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 67/209 reads (32%) | called by muse, mutect2, varscan2
- CAP2 | c.501T>C p.T167= | Silent (SNP) | VAF 46/121 reads (38%) | called by muse, mutect2, varscan2
- DCLRE1A | c.1899T>C p.R633= | Silent (SNP) | VAF 77/214 reads (36%) | called by muse, mutect2, varscan2
- FCGBP | c.10593G>C p.P3531= | Silent (SNP) | VAF 53/164 reads (32%) | called by muse, mutect2, varscan2
- GHDC | c.339G>A p.Q113= | Silent (SNP) | VAF 314/806 reads (39%) | called by muse, varscan2
- GPR45 | c.267C>G p.P89= | Silent (SNP) | VAF 231/496 reads (47%) | called by muse, mutect2, varscan2
- KDM4B | c.1791G>C p.P597= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV99347535; called by muse, mutect2, varscan2
- LILRB2 | c.324G>A p.E108= | Silent (SNP) | VAF 109/350 reads (31%) | called by muse, mutect2, varscan2
- RYR1 | c.12252T>C p.R4084= | Silent (SNP) | VAF 93/285 reads (33%) | called by muse, mutect2, varscan2
- TLN1 | c.4083G>A p.K1361= | Silent (SNP) | VAF 44/173 reads (25%) | catalogued as rs780092147; called by muse, mutect2, varscan2
- ZFHX3 | c.2886C>T p.G962= | Silent (SNP) | VAF 58/237 reads (24%) | catalogued as rs1275250227, COSV51707910; called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640512 T>A | 3'Flank (SNP) | VAF 84/326 reads (26%) | called by muse, mutect2, varscan2
- NDUFA10 | c.999+6540T>A | Intron (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2
